Surgical pathology report (de-identified scan), TCGA case TCGA-66-2759, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2759-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lower lobe, among others

Clinical diagnosis and question

Space-occupying lesion left lower lobe S6, (poorly differentiated large-cell, nonkeratinizing squamous cell carcinoma), status post asbestos exposure.

REPORT ON FINDINGS**Macroscopy**

- 1.) Left lower lobe: inflated, fixed left lower lobe of lung measuring 20 x 15 cm at the base and up to 17 cm in length, central bronchus resection plane located 0.3 cm proximal to the bifurcation of B6. A 7 cm long branched staple suture line runs in a ventrocaudal direction from the hilus. In the medioventral region over S6 a cusp-shaped part of the upper lobe measuring 4 x 1.5 x 1.2 cm is attached, closed by a staple suture line. In the laterodorsal region over S6 and adjacent sections of S10, part of the parietal pleura, measuring 9.5 x 5.5 cm, is mostly adhesive over an extensive area and loosely attached in parts at the margin. At the hilus are 3 mobile grayish-black nodes between 0.2 and 0.7 cm in size. Ostium of B6 completely obstructed by endobronchial parts of a central, moderately solid, pale brownish, focally soft tumor, max. 6 cm in size, located in S6, with unclear demarcation and extending right up to the ventral visceral pleura over S6 and to within 0.2 cm of the hilar resection surface. Apparent central involvement of some grayish-black parabronchial nodes up to 1.5 cm in size by the tumor. Macroscopically questionable infiltration of the attached part of the upper lobe, minimal distance from the resection plane of the pulmonary wedge after removal of the metal staple line 0.3 cm. Parenchyma peripheral to the tumor in S6 and adjacent sections of S10 right up to the dorsal pleura and to the pleural adhesion area over S6, with unclear demarcation, shows diffuse induration and a brownish-yellow color. Rest of parenchyma inconspicuous. Medially in the attached fatty tissue close to the basal margin are 4 grayish-black nodes between 0.2 and 1.1 cm in size.
- 2.) Peribronchial tissue left: 0.9 cm flat reddish tissue.
- 3.) Hilar LN (station 10) left: 1.4 cm grayish-black node or node part with some surrounding tissue.
- 4.) Pulmonary ligament LN (station 9) left: 2.2 cm grayish-black node with some surrounding tissue, section surfaces partly indurated and pale grayish-white suggestive of tumor.
- 5.) Paraesophageal LN (station 8) left: two 2.5 cm specimens of fatty tissue, containing 1 cm node with section surfaces suggestive of tumor.
- 6.) Paraaortic LN (station 6): 1.2 cm node part with some surrounding tissue.
- 7.) Subaortic LN (aortopulmonary window) (station 5): two lesioned grayish-black nodes or node parts with some surrounding tissue, 1.5 and 0.8 cm in size.

[page 2 of 2]
Examined:

- 1.) Rapid section remains and resection margins of vessels and hilar nodes, tumor with remaining parenchyma, endobronchial tumor part in B6, tumor with ventral visceral pleura over S6, 3 sections of hilar resection surface (color-marked), 2 sections with attached upper lobe part (resection plane after removal of staple suture line color-marked), brownish-yellow parenchyma and pleural adhesion zone, S10 dorsal, node in basal fatty tissue, 2 further sections with attached upper lobe part (resection plane after removal of staple suture line color-marked),
- 2.) Rapid section remains,
- 3.), 4.), 6.) + 7.) All material (in 4.) + 6.) nodes halved or multi-segmented, in 7.) nodes isolated),
- 5.) Nodes (halved),
- 17 blocks, partly Elastica-van Gieson, PAS, diastase-PAS, iron staining.

Microscopy

Re 1.) Immediate intraoperative evaluation (): bronchus resection margin tumor-free.

Re 2.) Immediate intraoperative evaluation (): fatty tissue supplied by vessels and nerves shows scarring, but no evidence of tumor. After paraffin embedding:

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION

Primary diagnosis/diagnoses:

Central to peripheral, histologically poorly differentiate, large-cell, nonkeratinizing squamous cell carcinoma of the lower lobe of the left lung located in S6.

TNM classification according to this picture pT2 pN2 pMX R0, stage IIIA.

C 34.3, M 8070/3.

Secondary diagnosis/diagnoses:

Advanced, active, small foci of colliquating, chronic organizing and focal retention pneumonia accompanied by fibrous remodeling of the parenchyma peripheral to the tumor associated with a pleural adhesion zone (sample 1.)). Hilar lymph nodes of the main preparation and lymph nodes of samples 6.) and 7.) with uncharacteristic reactive lesions, anthracotic pigment deposits and an old, nodular, cicatricially encapsulated area of necrosis (sample 6.)).

Remark/addendum:

The tumor has obstructed B6 at its bifurcation, continuously infiltrated parabronchial lymph nodes and extended focally to within at least 0.2 mm of the hilar resection surface. It has also grown across the pleural fissure initially and into the co-resected tissue from the upper lobe and has formed further lymph node metastases in samples 3.) - 5.). The resection lines of the bronchus and vessels, the resection plane of the wedge resection specimen from the upper lobe and the lymph nodes located at the hilus of the main preparation (sample 1)), the repeat resection specimen of sample 2.) and the lymph nodes of samples 6.) and 7.) are tumor-free.

No asbestos bodies are found in the prepared section planes. However, very much further-reaching investigations, in particular dust analytical studies, are needed to settle the question of asbestos dust exposure.

Source: NCI Genomic Data Commons file 0b7f4e59-7be9-44a1-9df3-46633a7acb9b (TCGA-66-2759.ADC593C7-44FC-4059-A161-A80B267DB72A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).